Gene-level copy-number profile of tumor specimen MP2PRT-PAXMWW-TTM2-A from MP2PRT case MP2PRT-PAXMWW, project MP2PRT-WT (Molecular Profiling to Predict Response to Treatment - Wilms Tumor). Sex at birth: female; Vital status: Alive; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 15.7 years (5,734 days).
Specimen MP2PRT-PAXMWW-TTM2-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 284930e1-c21f-4728-835a-8ac183b08e82.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAXMWW-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/4094c860-0dba-48a9-bccd-127079df45ea

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,936; copy number 2: 48,791; copy number 3: 5,811; copy number 4: 20; copy number 5: 571; copy number 6: 1,129; copy number 7: 138.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,838 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:97,933,474–98,272,658, 6 genes, copy number 7: MIR137HG, BX005019.1, MIR2682, MIR137, NFU1P2, LINC01776.
- chr1:143,419,625–180,519,119, 1,197 genes, copy number 6–7 (broad region; genes not listed).
- chr16:5,207,088–14,694,308, 178 genes, copy number 5–6 (broad region; genes not listed).
- chr16:14,974,591–15,139,339, 1 gene, copy number 5 (within-gene range 4–5): PDXDC1.
- chr16:15,037,854–16,398,594, 51 genes, copy number 5: NTAN1, RRN3, AC139256.1, NPIPP1, PKD1P6-NPIPP1, PKD1P6, MIR6511B2, Y_RNA, MIR3180-4, AC126763.1, AC137803.1, NPIPA5, MPV17L, AC140504.1, BMERB1, MARF1, AC026401.1, MIR6506, NDE1, MIR484, AC026401.2, AC026401.3, MYH11, AF001548.2, AF001548.1, AF001548.3, CEP20, RNU6-213P, AC130651.1, RPL15P20, ABCC1, RPL17P40, ABCC6, AC136624.1, NOMO3, AC136624.3, AC136624.2, MIR3179-2, MIR3670-2, AC138969.2, MIR3180-2, PKD1P1, Y_RNA, AC138969.1, MIR6511A2, MIR6770-2, AC138969.3, PKD1P2, MIR6511A3, NPIPA7, AC136619.1.
- chr16:16,541,217–20,797,581, 103 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr16:34,120,470–55,956,031, 302 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,936. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
